Somatic mutation profile of tumor specimen TCGA-02-0033-01A (aliquot TCGA-02-0033-01A-01D-1490-08) from TCGA case TCGA-02-0033, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,070 days).
Specimen TCGA-02-0033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04da0baa-6e34-4d1a-98e2-847d1c4a4bb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-0033-10A (Blood Derived Normal), aliquot TCGA-02-0033-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a84008d1-f3b6-43f3-b60a-52c13c6bc4bb

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as rs1131690865, CM030513, CM127815, COSV57307527, COSV57329700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ACADS | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1267288663, CM083801, COSV54370233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67230718; called by muse, varscan2
- ANKRD52 | c.2267C>T p.T756M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771081273, COSV57283454; called by muse, mutect2, varscan2
- CETP | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52364297; called by muse, mutect2, varscan2
- CFAP251 | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs868354554, COSV56615731; called by muse, mutect2, varscan2
- DPF1 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1290871639, COSV62793858; called by muse, mutect2, varscan2
- FAM219A | c.466G>A p.D156N (on ENST00000445726; = p.D139N on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1012132464, COSV52622491; called by muse, mutect2, varscan2
- FBXO16 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV60777152; called by muse, mutect2, varscan2
- FGFR2 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as COSV60654224; called by muse, mutect2, varscan2
- GARRE1 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs964434157, COSV55101882; called by muse, mutect2, varscan2
- HLTF | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV59503580; called by muse, mutect2
- HRH2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1299332797, COSV51576187; called by muse, varscan2
- ITGA7 | c.3541G>A p.A1181T (on ENST00000555728; = p.A1137T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772419744, COSV57693371; called by mutect2, varscan2
- SEMA3C | c.20G>T p.C7F | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54855111; called by muse, mutect2, varscan2
- SLC22A9 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs776740117, COSV54165789; called by muse, mutect2, varscan2
- SLC9C1 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs377402243; called by muse, mutect2, varscan2
- TAF4 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs767666911, COSV53340922; called by muse, mutect2, varscan2
- TNFSF11 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.263); catalogued as rs1450207753, COSV53478747; called by muse, mutect2, varscan2
- TSKU | c.257T>G p.L86W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60752814; called by muse, mutect2, varscan2
- ZNF99 | c.2066T>A p.F689Y | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.527); catalogued as COSV68056683; called by muse, mutect2, varscan2
- CCN1 | c.548_550dup p.L183_G184insV | In Frame Ins (INS) | VAF 38/217 reads (18%) | called by mutect2, pindel, varscan2
- GPR19 | c.1228_1236del p.P410_N412del | In Frame Del (DEL) | VAF 16/105 reads (15%) | called by mutect2, pindel, varscan2
- EGFL7 | c.516C>T p.D172= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs374085521; called by muse, mutect2, varscan2
- HCN4 | c.3528G>A p.G1176= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV56087138; called by muse, mutect2, varscan2
- ITGAD | c.387G>A p.S129= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs750617929, COSV66757365; called by muse, mutect2, varscan2
- ITGB4 | c.1578C>T p.Y526= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs563096686, COSV52329867; called by muse, mutect2, varscan2
- KRTAP6-3 | c.15C>A p.T5= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV66963378; called by muse, mutect2, varscan2
- LIN9 | c.1350C>T p.P450= (on ENST00000366808 / NM_001270410.2; = p.P395= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as COSV60246956; called by muse, mutect2, varscan2
- PCDHA1 | c.2034G>A p.A678= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs562110007, COSV65375424; called by muse, mutect2, varscan2
- PDIA4 | c.1155C>T p.A385= (on ENST00000286091 / NM_001371244.1; = p.A384= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV53726772; called by muse, mutect2, varscan2
- TMEM241 | c.825G>A p.T275= | Silent (SNP) | VAF 29/182 reads (16%) | catalogued as rs754517098, COSV67245655; called by muse, mutect2, varscan2
- TSPOAP1 | c.5400G>T p.V1800= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV52113739; called by muse, mutect2, varscan2
